CCDI case PBBIBR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1737be46-5f52-4575-8fea-b02a43d6dace

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.9 years (4,702 days).

Biospecimens (3 samples)
- Sample 0D8XGG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D8XGH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D8XGI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
